Surgical pathology report (de-identified scan), TCGA case TCGA-CS-5394, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-5394-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. LEFT FRONTAL TUMOR: ANAPLASTIC ASTROCYTOMA, WHO GRADE III, SEE MICROSCOPIC DESCRIPTION.
2. LEFT FRONTAL TUMOR: ATYPICAL GLIAL CELLS CONSISTENT WITH PORTION OF INFILTRATING ASTROCYTOMA, SEE DIAGNOSIS FOR SPECIMEN #1.

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of pleomorphic glial cells with eosinophilic cytoplasm and moderately pleomorphic nuclei with ovoid to angular contours. Multiple mitotic figures are identified in tumor cells (slide 1B). The proliferation index as determined by nuclear staining with the Ki67 (MIB-1) immunohistochemical stain is focally 10% in areas of tumor on slide 1B.

Frozen Section Diagnosis:

1. LEFT FRONTAL TUMOR: Glial neoplasm, final grading deferred to permanents.
2. LEFT FRONTAL TUMOR: Glial neoplasm. No clear anaplastic features identified in this material. Frozen section diagnosis

[page 2 of 3]
Clinical History and Diagnosis:

Left frontal tumor consistent with glioma. Nonenhancing lesion.

Source of Specimen:

1: LEFT FRONTAL TUMOR

2: LEFT FRONTAL TUMOR

Gross Description:

1. LEFT FRONTAL TUMOR: Received fresh for frozen section are multiple fragments of soft tan pink tissue measuring 1.5 of 1.5 x 0.6cm in aggregate. Touch preps are made. Half of the specimen is submitted for frozen section diagnosis, the remaining specimen is submitted for permanent sections.

2. LEFT FRONTAL TUMOR: Received fresh for frozen section are multiple fragments of soft tan white tissue measuring 0.4 x 0.2 x 0.2cm in aggregate. Touch preps are made. Half of the specimen is submitted for frozen section diagnosis. The remaining specimen is submitted for permanent sections.

Histology Laboratory

H&E

Part 1: LEFT FRONTAL TUMOR

UNSTAINED

[page 3 of 3]
[REDACTED]

[REDACTED]

IMMUNOPATHOLOGY REPORT

EVALUATION:

Ki67: POSITIVE STAINING IN UP TO 10% OF TUMOR CELL NUCLEI.

GFAP: POSITIVE STAINING IN TUMOR.

CHROMOGRANIN: NEGATIVE IN TUMOR CELLS.

Comment:

The immunohistochemical stains support the diagnosis of Anaplastic Astrocytoma, WHO grade III. See corresponding surgical pathology report [REDACTED].

[REDACTED] [REDACTED]
[REDACTED] [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.
[REDACTED]

Source: NCI Genomic Data Commons file 10ecb378-9f5d-48e0-ab73-19708ab34ac2 (TCGA-CS-5394.E2716CB5-E02C-4867-BA99-FE8337878D9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).